Somatic mutation profile of tumor specimen TCGA-18-3414-01A (aliquot TCGA-18-3414-01A-01D-0983-08) from TCGA case TCGA-18-3414, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 73.8 years (26,938 days).
Specimen TCGA-18-3414-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19d0497f-eb00-4972-88db-00e185796d2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-3414-11A (Solid Tissue Normal), aliquot TCGA-18-3414-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f305b60-d2bb-4e12-bf72-838d5e4e593a

The open-access MAF lists 340 somatic variants for this specimen: 270 protein-altering or splice-affecting, 65 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 229, Silent 65, Nonsense Mutation 23, Frame Shift Ins 5, Frame Shift Del 4, Splice Site 4, Intron 3, Splice Region 2, Translation Start Site 2, In Frame Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.4390C>T p.R1464* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs912671116, COSV55090355; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 13/22 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.385); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4744C>T p.P1582S (on ENST00000272895 / NM_173076.3; = p.P1264S on NM_015657.3) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.118); catalogued as COSV55978327; called by muse, mutect2, varscan2
- ABCC11 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773385493, COSV62326269; called by muse, mutect2, varscan2
- ACOT7 | c.832A>G p.I278V (on ENST00000377855 / NM_181864.3; = p.I268V on NM_007274.4) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.322); catalogued as COSV64115002; called by muse, mutect2, varscan2
- ADCY8 | c.2960C>A p.S987Y | Missense Mutation (SNP) | VAF 65/125 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV53916194, COSV53931169; called by muse, mutect2, varscan2
- ADGRB1 | c.4430A>G p.Y1477C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60103973; called by muse, mutect2, varscan2
- AKAP6 | c.611C>G p.S204* | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as COSV55236026; called by muse, mutect2
- ANGPTL5 | c.1103C>A p.S368* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as COSV57534825; called by muse, mutect2, varscan2
- ANKLE2 | c.741G>C p.E247D | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV61712026; called by muse, mutect2, varscan2
- APBB1IP | c.1116G>A p.M372I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.035); catalogued as COSV66130583; called by muse, mutect2, varscan2
- APLF | c.1211A>T p.Y404F | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV58149463; called by muse, mutect2, varscan2
- APOL5 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV50769034; called by muse, mutect2
- ASCC3 | c.2758A>G p.T920A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV61234556; called by muse, mutect2
- ATP10B | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs751974766, COSV58777633; called by muse, mutect2, varscan2
- ATP10D | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV56713964; called by muse, mutect2
- BCAN | c.2000G>T p.G667V | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as COSV61257083; called by muse, mutect2, varscan2
- BNC2 | c.1772C>A p.T591N | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV66158740; called by muse, mutect2, varscan2
- BPIFA1 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as rs1337730552, COSV62825130, COSV62825351; called by muse, mutect2, varscan2
- C5AR2 | c.445T>A p.C149S | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0.154); catalogued as COSV57257513; called by muse, mutect2, varscan2
- C6orf58 | c.566T>C p.F189S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61667490; called by muse, mutect2, varscan2
- C8orf34 | c.1456G>C p.D486H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); catalogued as COSV57414521; called by muse, mutect2, varscan2
- CADPS2 | c.2631G>T p.E877D | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57389041; called by muse, mutect2, varscan2
- CCDC172 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV60940753; called by muse, mutect2, varscan2
- CCDC85A | c.1534C>G p.P512A | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); catalogued as COSV68148619, COSV68156051; called by muse, mutect2, varscan2
- CCDC88A | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55070982; called by muse, mutect2, varscan2
- CCL3 | c.273T>A p.S91R | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs1266347420; called by muse, mutect2, varscan2
- CDH18 | c.883G>C p.A295P | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.049); catalogued as COSV56966733; called by muse, mutect2, varscan2
- CDH26 | c.2239A>G p.M747V (on ENST00000348616 / NM_177980.4; = p.M80V on NM_021810.6) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54856663; called by muse, mutect2, varscan2
- CDHR1 | c.1945G>T p.D649Y | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60567039; called by muse, mutect2, varscan2
- CELSR1 | c.4201G>C p.D1401H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV53101365, COSV99420038; called by muse, mutect2, varscan2
- CFAP47 | c.892G>C p.D298H | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.725); catalogued as COSV52892733; called by muse, mutect2, varscan2
- CHD4 | c.3620A>G p.K1207R (on ENST00000357008 / NM_001363606.2; = p.K1220R on NM_001273.5) | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.987); catalogued as COSV58912223; called by muse, mutect2, varscan2
- CLDN6 | c.19C>A p.Q7K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs764277596, COSV58510857; called by muse, mutect2, varscan2
- CLEC1A | c.698G>A p.S233N | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV59534275; called by muse, mutect2, varscan2
- CLSTN2 | c.2357A>C p.E786A | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs776372790, COSV71725613; called by muse, mutect2, varscan2
- CNTNAP5 | c.3903A>C p.K1301N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV70515536; called by muse, mutect2, varscan2
- COL3A1 | c.4313G>T p.R1438I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58597813; called by muse, mutect2, varscan2
- COX7B2 | c.215G>T p.R72I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57223998; called by muse, mutect2, varscan2
- CREB3 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.222); catalogued as rs771918577, COSV59212361; called by muse, mutect2, varscan2
- CRPPA | c.797A>G p.Y266C (on ENST00000407010 / NM_001368197.1; = p.Y216C on NM_001101417.4) | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67909172; called by muse, mutect2, varscan2
- CSMD2 | c.3839C>T p.S1280L | Missense Mutation (SNP) | VAF 75/153 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs528971870, COSV53970542; called by muse, mutect2, varscan2
- CSMD3 | c.10951C>T p.L3651F (on ENST00000297405 / NM_001363185.1; = p.L3482F on NM_052900.3) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52203364, COSV52339860; called by muse, mutect2, varscan2
- CSMD3 | c.10950T>A p.Y3650* (on ENST00000297405 / NM_001363185.1; = p.Y3481* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV52339881, COSV99846335; called by muse, mutect2, varscan2
- CSMD3 | c.4249C>T p.R1417C (on ENST00000297405 / NM_001363185.1; = p.R1313C on NM_052900.3) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as rs762798837, COSV52206340; called by muse, mutect2, varscan2
- CT83 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as COSV64140914, COSV64141554; called by muse, mutect2, varscan2
- CTDP1 | c.2211G>T p.R737S | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50000609, COSV50009844; called by muse, mutect2, varscan2
- CTLA4 | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99865097; called by muse, mutect2, varscan2
- DBNL | c.1276G>A p.V426M (on ENST00000448521 / NM_001014436.3; = p.V427M on NM_014063.7) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765506722, COSV51979911; called by muse, mutect2, varscan2
- DCAF4L2 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100150671, COSV60476277, COSV60478817; called by muse, mutect2, varscan2
- DCAF4L2 | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV60483240; called by muse, mutect2, varscan2
- DCHS1 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs765079321, COSV55043806; called by muse, mutect2, varscan2
- DCTN1 | c.2516C>T p.A839V | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV62621651; called by muse, mutect2, varscan2
- DCX | c.931G>A p.G311S (on ENST00000636035 / NM_001195553.2; = p.A311T on NM_000555.3) | Missense Mutation (SNP) | VAF 81/113 reads (72%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100576764, COSV57576133; called by muse, mutect2, varscan2
- DGCR2 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); catalogued as COSV54222964; called by muse, mutect2, varscan2
- DHX15 | c.299C>G p.S100* | Nonsense Mutation (SNP) | VAF 39/118 reads (33%) | catalogued as COSV61029546; called by muse, mutect2, varscan2
- DIAPH3 | c.770A>T p.Q257L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV57382816; called by muse, mutect2, varscan2
- DIDO1 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as COSV56635373; called by muse, mutect2, varscan2
- DIS3L | c.2356G>A p.G786S (on ENST00000319212 / NM_001143688.3; = p.G703S on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761483425, COSV59914745; called by muse, mutect2, varscan2
- DMTN | c.900G>C p.R300= | Splice Region (SNP) | VAF 53/119 reads (45%) | catalogued as COSV56112606, COSV56114871; called by muse, mutect2, varscan2
- DNMT3A | c.1598A>G p.Y533C | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV53037384; called by muse, mutect2, varscan2
- DPP9 | c.401T>G p.L134R (on ENST00000598800; = p.L163R on NM_139159.5) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs906121745; called by mutect2, varscan2
- DSCAML1 | c.2836+2T>A p.X946_splice (on ENST00000321322; = p.X886_splice on NM_020693.4) | Splice Site (SNP) | VAF 6/33 reads (18%) | catalogued as COSV58400603, COSV58404311; called by muse, mutect2, varscan2
- DYNC2LI1 | c.253T>C p.W85R | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53185669; called by muse, mutect2, varscan2
- EED | c.1116C>A p.F372L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV54558865; called by muse, mutect2, varscan2
- EEF1AKNMT | c.792G>T p.R264S (on ENST00000361735 / NM_015935.5; = p.R178S on NM_014955.3) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV62283979; called by muse, mutect2, varscan2
- EIF2AK3 | c.3265A>G p.R1089G | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV57552784; called by muse, mutect2, varscan2
- EREG | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV55262838; called by muse, mutect2, varscan2
- ERN2 | c.1296C>A p.D432E | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV56838559; called by muse, mutect2, varscan2
- FAM135B | c.3438T>A p.H1146Q | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52757121; called by muse, mutect2, varscan2
- FAM155A | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV65590575; called by muse, mutect2, varscan2
- FAM169A | c.736G>C p.G246R | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65847472; called by muse, mutect2, varscan2
- FAM71F1 | c.614C>G p.T205S | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV59375103; called by muse, mutect2, varscan2
- FCRL1 | c.200G>T p.S67I | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV63827897; called by muse, mutect2, varscan2
- FPR2 | c.284G>C p.W95S | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV60674663; called by muse, mutect2, varscan2
- FTMT | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs1446498758, COSV58419511; called by muse, mutect2, varscan2
- GAD2 | c.1163A>T p.N388I | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV52170113; called by muse, mutect2, varscan2
- GALNTL5 | c.683G>T p.S228I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67181427; called by muse, mutect2, varscan2
- GANAB | c.409A>T p.S137C | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV60469124; called by muse, mutect2, varscan2
- GCLC | c.1046A>G p.D349G (on ENST00000643939; = p.D347G on NM_001498.4) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.599); catalogued as COSV57598168; called by muse, mutect2, varscan2
- GIMAP8 | c.1095G>C p.R365S | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100217612, COSV56234662; called by muse, mutect2, varscan2
- GJA1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56999861; called by muse, mutect2, varscan2
- GLRA1 | c.437T>A p.L146Q | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51027413; called by muse, mutect2, varscan2
- GLS | c.1525G>T p.G509C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57845574; called by muse, mutect2, varscan2
- GPR137B | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as rs775789454, COSV63991546; called by muse, mutect2, varscan2
- GPR158 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as COSV66284622; called by muse, mutect2
- GPRC5A | c.680G>T p.W227L | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50008920; called by muse, mutect2, varscan2
- GRIN2B | c.2021C>G p.P674R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74208279; called by muse, mutect2, varscan2
- H3C2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV52517721, COSV52518221; called by muse, mutect2, varscan2
- HELB | c.697A>T p.I233L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV56076555; called by muse, mutect2, varscan2
- IGDCC4 | c.2189T>G p.V730G | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV61539591; called by muse, mutect2, varscan2
- IGF2R | c.4358T>A p.L1453Q | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63633416; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.9G>T p.W3C | Missense Mutation (SNP) | VAF 60/396 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as rs1340838312; called by mutect2, varscan2
- IGKV1-17 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs77497402; called by muse, varscan2
- IGKV3-15 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.177); catalogued as rs568392727; called by muse, mutect2, varscan2
- ITGA8 | c.2662C>T p.P888S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV100959007, COSV65237271; called by muse, mutect2, varscan2
- KANSL3 | c.1157G>A p.R386K | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV62624346; called by muse, mutect2, varscan2
- KCNJ1 | c.1023C>A p.F341L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.363); catalogued as COSV60663165; called by muse, mutect2, varscan2
- KHDC1 | c.550C>G p.L184V (on ENST00000370384 / NM_001251874.2; = p.L111V on NM_030568.5) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV57616357; called by muse, mutect2
- KIF21B | c.4301C>T p.A1434V (on ENST00000422435 / NM_001252100.2; = p.A1421V on NM_017596.4) | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV59768012; called by muse, mutect2, varscan2
- KIFAP3 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV63037863; called by muse, mutect2
- KLHL9 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV62922514; called by muse, mutect2, varscan2
- KLKB1 | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1207954946, COSV53000020; called by muse, mutect2, varscan2
- KMT2D | c.15149T>G p.L5050R | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56492698; called by muse, mutect2
- KRTAP5-6 | c.118T>G p.C40G | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV66289422; called by muse, mutect2, varscan2
- L3MBTL3 | c.42T>A p.D14E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62389264; called by muse, mutect2, varscan2
- LEMD3 | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV57654364; called by muse, mutect2, varscan2
- LEPR | c.1270G>T p.E424* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV60766067; called by muse, mutect2, varscan2
- LHCGR | c.1346_1347insG p.S450Kfs*2 | Frame Shift Ins (INS) | VAF 18/129 reads (14%) | catalogued as COSV99683245; called by mutect2, pindel, varscan2
- LILRB5 | c.1242G>C p.E414D | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV60261523; called by muse, mutect2, varscan2
- LRP1B | c.12802C>A p.L4268I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as COSV67189226, COSV67281237; called by muse, mutect2, varscan2
- LRP1B | c.5458G>A p.G1820R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.976); catalogued as COSV67281242; called by muse, mutect2, varscan2
- LRRC8D | c.1561T>C p.C521R | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs112842021, COSV61581562; called by muse, mutect2, varscan2
- LTBP1 | c.3259A>G p.N1087D (on ENST00000404816 / NM_206943.4; = p.N761D on NM_000627.4) | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated (0.34); PolyPhen benign (0.312); catalogued as COSV55386515; called by muse, mutect2, varscan2
- LUZP1 | c.1873G>C p.E625Q | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV56501990, COSV56505977; called by muse, mutect2, varscan2
- LYST | c.10941-2A>T p.X3647_splice | Splice Site (SNP) | VAF 24/49 reads (49%) | catalogued as COSV67715113; called by muse, mutect2, varscan2
- MACF1 | c.12790C>T p.L4264F (on ENST00000372915; = p.L2197F on NM_012090.5) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as rs780577130, COSV57148003; called by muse, mutect2, varscan2
- MAGEB1 | c.955T>A p.S319T | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.483); catalogued as COSV66776756; called by muse, mutect2, varscan2
- MAP4K4 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs868663062, COSV56341920; called by muse, mutect2, varscan2
- MCM5 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV53348624; called by muse, mutect2, varscan2
- METTL17 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772938639, COSV53871298; called by muse, mutect2, varscan2
- METTL2B | c.1120C>G p.L374V | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52311475, COSV99299821; called by muse, mutect2, varscan2
- MGAT5 | c.1753G>C p.E585Q | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV56101725; called by muse, mutect2
- MNS1 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53070708; called by muse, mutect2, varscan2
- MSH4 | c.1343C>A p.A448D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV54213595, COSV54213904; called by muse, mutect2, varscan2
- MYH15 | c.3668A>T p.Q1223L | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56321327; called by muse, mutect2, varscan2
- MYH7B | c.1181A>G p.Y394C | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746815628, COSV53426008, COSV53426339; called by muse, mutect2, varscan2
- MYO16 | c.2978G>T p.S993I | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV51821562; called by muse, mutect2, varscan2
- MYO1H | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs776577000, COSV60451915; called by muse, mutect2, varscan2
- MYOC | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as rs1351097164, COSV50677257; called by muse, mutect2, varscan2
- NCOA3 | c.347T>G p.L116R | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59074183; called by muse, mutect2
- NDUFV2 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59188324; called by muse, mutect2
- NEB | c.11938A>G p.M3980V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51465349; called by muse, mutect2
- NEXMIF | c.1034G>T p.C345F | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1362175878, COSV50030044; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NID2 | c.1310del p.P437Qfs*22 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | catalogued as rs761668313; called by mutect2, pindel, varscan2
- NKAP | c.1031T>G p.I344S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65057073; called by muse, mutect2, varscan2
- NLRP5 | c.79A>T p.T27S | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.221); catalogued as COSV101173824, COSV66767895; called by muse, mutect2, varscan2
- NLRP6 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 29/52 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV56462365; called by muse, mutect2, varscan2
- NTM | c.710A>C p.Q237P | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV66196851; called by muse, mutect2, varscan2
- NUP133 | c.2745A>T p.L915F | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV54575843; called by muse, mutect2, varscan2
- OBSCN | c.5018G>T p.R1673L | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as COSV52838635; called by muse, mutect2, varscan2
- OCA2 | c.1246C>G p.R416G | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV62348970, COSV62359421; called by muse, mutect2, varscan2
- OCM2 | c.15C>A p.D5E | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.351); catalogued as COSV57535963; called by muse, mutect2, varscan2
- OR14J1 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV65846010; called by muse, mutect2, varscan2
- OR2G2 | c.842A>T p.Y281F | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60742621; called by muse, mutect2, varscan2
- OR2L8 | c.566T>A p.M189K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.102); catalogued as COSV61726612, COSV61728672; called by muse, mutect2, varscan2
- OR2L8 | c.567G>T p.M189I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV61728681; called by muse, mutect2, varscan2
- OR2T10 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV100393586; called by muse, mutect2, varscan2
- OR4A15 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.734); catalogued as rs746946575, COSV59038190; called by muse, mutect2, varscan2
- OR4X2 | c.821T>C p.L274P | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56585431; called by muse, mutect2, varscan2
- OR52B2 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV73209703; called by muse, mutect2, varscan2
- OR52E4 | c.11T>C p.I4T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV57626542; called by muse, mutect2, varscan2
- OR52E8 | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66213507; called by muse, mutect2
- OR5A1 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 45/134 reads (34%) | catalogued as rs199856591, COSV57377870; called by muse, mutect2, varscan2
- OSMR | c.1459C>G p.P487A | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as rs774909812, COSV57092979; called by muse, mutect2, varscan2
- PAPOLB | c.1068G>T p.K356N | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV68200850, COSV68204032; called by muse, mutect2, varscan2
- PBDC1 | c.576G>C p.E192D | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.054); catalogued as COSV64896295; called by muse, mutect2, varscan2
- PCDH15 | c.4616A>G p.E1539G | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.97); catalogued as COSV64746135; called by muse, mutect2
- PCDH8 | c.2693G>C p.G898A | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV58815332; called by muse, mutect2, varscan2
- PCDHB13 | c.542T>A p.V181D | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV53401689; called by muse, mutect2, varscan2
- PCLO | c.10364G>A p.R3455Q | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as rs756859068, COSV61634372; called by muse, mutect2, varscan2
- PCMTD1 | c.246G>C p.L82F | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV62123099, COSV62126188; called by muse, mutect2, varscan2
- PGM2L1 | c.563G>A p.W188* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV53348173, COSV53350288; called by muse, mutect2, varscan2
- PHACTR2 | c.1339G>T p.G447W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59860154; called by muse, mutect2, varscan2
- PIAS3 | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65172234; called by muse, mutect2, varscan2
- PICALM | c.1273A>G p.T425A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV62674719; called by muse, mutect2, varscan2
- PLXNB2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63784930; called by muse, mutect2, varscan2
- PNPLA6 | c.3888G>C p.E1296D (on ENST00000414982 / NM_001166111.2; = p.E1248D on NM_006702.5) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55386272; called by muse, mutect2, varscan2
- POLR2D | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | catalogued as COSV55759324; called by muse, mutect2, varscan2
- POSTN | c.1610C>A p.T537N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV65714952; called by muse, varscan2
- PPDPFL | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 78/150 reads (52%) | catalogued as rs1459429734, COSV57461760; called by muse, mutect2, varscan2
- PPFIA2 | c.1080G>A p.M360I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV61058407; called by muse, mutect2, varscan2
- PPP1R12B | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 74/170 reads (44%) | catalogued as COSV61124651; called by muse, mutect2, varscan2
- PPP1R14A | c.300T>G p.C100W | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56647038; called by muse, mutect2, varscan2
- PRKCB | c.1564G>T p.V522L | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57772729, COSV57776928; called by muse, mutect2, varscan2
- PWWP2B | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV59454105; called by mutect2, varscan2
- QRFPR | c.124G>T p.G42* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as COSV57680543; called by muse, mutect2, varscan2
- RALGAPA2 | c.4624C>G p.L1542V | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52513223; called by muse, mutect2, varscan2
- RANBP2 | c.7030A>G p.K2344E | Missense Mutation (SNP) | VAF 111/276 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV51709738; called by muse, mutect2, varscan2
- RASSF9 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63434743; called by muse, mutect2, varscan2
- RCAN1 | c.580G>T p.G194W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58252369; called by muse, mutect2, varscan2
- RFPL2 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.09); catalogued as COSV50719693; called by muse, mutect2, varscan2
- RHBDD1 | c.692A>C p.Q231P | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV58132236; called by muse, mutect2, varscan2
- RIC1 | c.3608C>G p.S1203C | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV52616306; called by muse, mutect2, varscan2
- RIMS1 | c.3180C>G p.H1060Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV53488704; called by muse, mutect2
- RNF213 | c.7582C>T p.R2528W | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367919620; called by muse, mutect2, varscan2
- RREB1 | c.2866G>T p.A956S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as COSV58566825; called by muse, mutect2, varscan2
- RYR3 | c.8237G>A p.W2746* (on ENST00000389232; = p.W2747* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV101212799, COSV66810505; called by muse, mutect2, varscan2
- SAMD7 | c.699C>G p.S233R | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs1447954836, COSV59421945; called by muse, mutect2, varscan2
- SAMD9 | c.1483A>C p.N495H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66077943; called by muse, mutect2, varscan2
- SAP130 | c.1760G>C p.G587A | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV52103818; called by muse, mutect2, varscan2
- SCN1A | c.3627G>T p.R1209S (on ENST00000303395 / NM_001202435.3; = p.R1198S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV57690880; called by muse, mutect2, varscan2
- SCN1A | c.3626G>A p.R1209K (on ENST00000303395 / NM_001202435.3; = p.R1198K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57690903; called by muse, mutect2, varscan2
- SCN2A | c.3011A>G p.Q1004R | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as COSV51857540; called by muse, mutect2, varscan2
- SELENBP1 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.248); catalogued as COSV64374179, COSV64374295; called by muse, mutect2, varscan2
- SEMA5A | c.693C>G p.F231L | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV66789747, COSV66806994; called by muse, mutect2, varscan2
- SGCD | c.754C>A p.P252T (on ENST00000435422 / NM_001128209.2; = p.P253T on NM_000337.5) | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV61903259, COSV61917892; called by muse, mutect2, varscan2
- SHOX | c.625T>C p.F209L | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV61862551; called by muse, mutect2, varscan2
- SIGIRR | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58990431; called by muse, mutect2, varscan2
- SIRPA | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 58/130 reads (45%) | catalogued as COSV61541826; called by muse, mutect2, varscan2
- SIRPG | c.725C>G p.A242G | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV53810626; called by muse, mutect2, varscan2
- SLC2A11 | c.992T>C p.V331A (on ENST00000345044 / NM_001024938.4; = p.V338A on NM_030807.5) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.314); catalogued as COSV55394338; called by muse, mutect2
- SLC34A2 | c.1606T>A p.F536I | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1227346120, COSV65942763; called by muse, mutect2, varscan2
- SLC35C2 | c.257G>T p.R86I | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1295060402, COSV54756922, COSV54758696; called by muse, mutect2, varscan2
- SLC9A4 | c.1951-1G>A p.X651_splice | Splice Site (SNP) | VAF 39/128 reads (30%) | catalogued as rs1363306002, COSV54840089; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2006G>T p.G669V (on ENST00000540229 / NM_001371097.1; = p.G608V on NM_001009562.4) | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67451203; called by muse, mutect2, varscan2
- SLCO4A1 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775283350, COSV53894536; called by muse, mutect2, varscan2
- SLITRK3 | c.2039G>T p.R680L | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.353); catalogued as COSV53854217, COSV99579168; called by muse, mutect2, varscan2
- SOX14 | c.349G>C p.G117R | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs201978283, COSV60163549; called by muse, mutect2, varscan2
- SPHKAP | c.1187C>A p.A396E | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV60896640; called by muse, mutect2, varscan2
- SPHKAP | c.121A>G p.I41V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV60896653; called by muse, mutect2, varscan2
- SPTA1 | c.3490del p.R1164Afs*76 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as COSV63748550; called by mutect2, varscan2
- SRRM2 | c.1976G>T p.R659L | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.144); catalogued as COSV57069612; called by muse, mutect2, varscan2
- SRRM2 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.382); catalogued as COSV57081374; called by muse, mutect2, varscan2
- SRSF1 | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as COSV51966676; called by muse, mutect2, varscan2
- STK19 | c.878C>T p.P293L (on ENST00000375333 / NM_032454.1; = p.P289L on NM_004197.1) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100941619, COSV64692793; called by muse, mutect2, varscan2
- SUV39H1 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61921479; called by mutect2, varscan2
- SYNE1 | c.16016T>A p.V5339D (on ENST00000367255 / NM_182961.4; = p.V5268D on NM_033071.3) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV55121858; called by muse, mutect2, varscan2
- TAS2R16 | c.316A>G p.K106E | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50799041; called by muse, mutect2, varscan2
- TBC1D9 | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as COSV71309377; called by muse, mutect2
- TBX21 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs965811401, COSV51595325; called by muse, mutect2, varscan2
- TENM2 | c.5662C>A p.L1888M (on ENST00000518659 / NM_001122679.2; = p.L1649M on NM_001080428.3) | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV69143706; called by muse, mutect2, varscan2
- TENM4 | c.6845A>T p.N2282I | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53623825, COSV53676520; called by muse, mutect2, varscan2
- TFAP2D | c.1199C>A p.T400K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV50412477, COSV50466477, COSV99145834; called by muse, mutect2, varscan2
- TIMD4 | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs775298433, COSV50861405; called by muse, mutect2, varscan2
- TNNT1 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV52571541; called by muse, mutect2, varscan2
- TNR | c.2859G>T p.M953I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99687880; called by muse, mutect2, varscan2
- TNR | c.689G>A p.C230Y | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767647824, COSV54917201; called by muse, mutect2, varscan2
- TRPC3 | c.2193G>T p.M731I (on ENST00000379645 / NM_001366479.2; = p.M658I on NM_003305.2) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.619); catalogued as COSV53379437, COSV53379971; called by muse, mutect2, varscan2
- TRPC4 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV59021708; called by muse, mutect2, varscan2
- TTN | c.11681G>T p.G3894V (on ENST00000591111; = p.G3848V on NM_003319.4) | Missense Mutation (SNP) | VAF 18/97 reads (19%) | catalogued as COSV60277801, COSV60391577; called by muse, mutect2, varscan2
- TTN | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 25/72 reads (35%) | PolyPhen benign (0.293); catalogued as rs879185669, COSV60391605; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TULP3 | c.1241T>A p.F414Y | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68118891; called by muse, mutect2, varscan2
- UCHL3 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs139878255; called by mutect2, varscan2
- UGDH | c.777G>T p.Q259H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57100142; called by muse, mutect2, varscan2
- UGGT1 | c.2245T>A p.S749T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52142648; called by muse, mutect2, varscan2
- UGT1A3 | c.805A>G p.I269V | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0.042); catalogued as rs776377482, COSV59400500; called by muse, mutect2
- UPF2 | c.112A>T p.K38* | Nonsense Mutation (SNP) | VAF 52/107 reads (49%) | catalogued as COSV62664355; called by muse, mutect2, varscan2
- USP34 | c.7054G>C p.D2352H | Missense Mutation (SNP) | VAF 80/268 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV68407720; called by muse, varscan2
- UTRN | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV62349677; called by muse, mutect2, varscan2
- VPS53 | c.661G>A p.E221K (on ENST00000571805 / NM_001366253.2; = p.E192K on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV52139277; called by muse, varscan2
- WAPL | c.602C>G p.A201G | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.018); catalogued as COSV53940790; called by muse, mutect2, varscan2
- YIPF7 | c.498G>C p.L166= | Splice Region (SNP) | VAF 5/15 reads (33%) | catalogued as COSV60658345; called by muse, mutect2, varscan2
- YJU2 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV53608002; called by muse, mutect2, varscan2
- ZFAND1 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV55106873, COSV55108881; called by muse, mutect2, varscan2
- ZFHX4 | c.10419G>T p.E3473D | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as COSV51500113; called by muse, mutect2, varscan2
- ZFP91 | c.1250G>A p.W417* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as COSV60162481; called by muse, mutect2, varscan2
- ZHX2 | c.1904A>G p.K635R | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV58718138; called by muse, mutect2, varscan2
- ZNF28 | c.303G>A p.W101* | Nonsense Mutation (SNP) | VAF 62/204 reads (30%) | catalogued as COSV60425827; called by muse, mutect2, varscan2
- ZNF337 | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as COSV53323320; called by muse, mutect2, varscan2
- ZNF37A | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV61075892; called by muse, mutect2, varscan2
- ZNF440 | c.1162A>G p.R388G | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58372770; called by muse, mutect2, varscan2
- ZNF479 | c.509C>A p.S170* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as rs782705891, COSV58643490, COSV58644349; called by muse, mutect2, varscan2
- ZNF571 | c.1628C>G p.S543* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as COSV60734049, COSV60734890; called by muse, mutect2
- ZNF746 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.976); catalogued as COSV61406315; called by muse, mutect2, varscan2
- ZNF79 | c.130A>G p.T44A | Missense Mutation (SNP) | VAF 49/68 reads (72%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61072063; called by muse, mutect2, varscan2
- ZNF831 | c.2597C>T p.P866L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV64045896; called by muse, mutect2, varscan2
- ZSCAN31 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV60181755, COSV60181781; called by muse, mutect2, varscan2
- ABCB5 | c.3611del p.G1204Efs*5 (on ENST00000404938 / NM_001163941.2; = p.G759Efs*5 on NM_178559.6) | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- DPP9 | c.399_400insG p.L134Afs*73 (on ENST00000598800; = p.L163Afs*73 on NM_139159.5) | Frame Shift Ins (INS) | VAF 20/52 reads (38%) | called by mutect2, varscan2
- IGLV2-11 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 29/526 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2
- IQGAP1 | c.2130del p.P711Qfs*22 | Frame Shift Del (DEL) | VAF 52/106 reads (49%) | called by mutect2, pindel, varscan2
- NCAPG2 | c.710_712del p.I237del | In Frame Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.5924dup p.T1976Hfs*9 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- PRKCA | c.1492_1493insC p.F498Sfs*33 | Frame Shift Ins (INS) | VAF 43/80 reads (54%) | called by mutect2, pindel, varscan2
- SPATA7 | c.797dup p.D267Gfs*10 | Frame Shift Ins (INS) | VAF 21/56 reads (38%) | called by mutect2, pindel, varscan2
- TRAV7 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- ZMIZ1 | c.2836-1_2875del p.X946_splice | Splice Site (DEL) | VAF 4/52 reads (8%) | called by mutect2, pindel
- ABCB4 | c.2092C>T p.L698= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV55942749; called by muse, mutect2, varscan2
- ACOT7 | c.249A>T p.A83= (on ENST00000377855 / NM_181864.3; = p.A73= on NM_007274.4) | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV64115748; called by muse, mutect2, varscan2
- ADCY1 | c.1251C>T p.D417= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs142228376; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADGRF5 | c.3483C>T p.V1161= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV51941317; called by muse, mutect2, varscan2
- AHCTF1 | c.2478A>G p.T826= (on ENST00000366508; = p.T800= on NM_015446.5) | Silent (SNP) | VAF 48/93 reads (52%) | catalogued as COSV58256711; called by muse, mutect2, varscan2
- ALS2CL | c.1875C>T p.F625= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs200130846, COSV59670356; called by mutect2, varscan2
- BPIFA1 | c.57C>A p.A19= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV62825347; called by muse, mutect2, varscan2
- C5AR2 | c.444G>A p.A148= | Silent (SNP) | VAF 55/90 reads (61%) | catalogued as rs748064298, COSV57257168; called by muse, mutect2, varscan2
- CATSPERD | c.1149C>T p.H383= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs369741473; called by muse, mutect2, varscan2
- CDH4 | c.2181G>A p.A727= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs151300553; called by muse, mutect2
- CHAT | c.372C>T p.P124= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV60319450; called by muse, mutect2, varscan2
- CNR1 | c.675G>A p.K225= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs559393374, COSV62986555; called by muse, mutect2, varscan2
- CTNS | c.945G>A p.Q315= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV50444968; called by muse, mutect2, varscan2
- DDIT4 | c.561C>G p.P187= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV56578208; called by muse, mutect2, varscan2
- DGKD | c.504C>T p.A168= (on ENST00000264057 / NM_152879.3; = p.A124= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV51035698, COSV99895508; called by muse, mutect2
- DLGAP3 | c.1521C>T p.I507= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs938017397, COSV52398654; called by muse, mutect2, varscan2
- DNAH5 | c.5925G>T p.G1975= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as COSV54243443, COSV99445598; called by muse, mutect2, varscan2
- DPP10 | c.1827G>A p.L609= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV59736820; called by muse, mutect2, varscan2
- EIF3E | c.1032C>T p.F344= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV55201896, COSV55206357; called by muse, mutect2, varscan2
- F13A1 | c.930C>A p.V310= | Silent (SNP) | VAF 59/150 reads (39%) | catalogued as COSV53568980; called by muse, mutect2, varscan2
- FAM83D | c.1161T>C p.I387= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV54159450; called by muse, mutect2, varscan2
- FARP2 | c.2004G>A p.K668= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV50884302; called by muse, mutect2, varscan2
- FSHR | c.579C>A p.T193= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV58636739; called by muse, mutect2, varscan2
- GYS2 | c.1212C>G p.L404= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV53920133; called by muse, mutect2, varscan2
- HNRNPU | c.1377A>T p.A459= (on ENST00000283179; = p.A521= on NM_004501.3) | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as COSV51694808; called by muse, mutect2, varscan2
- HSPA12A | c.960C>T p.T320= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs374148558; called by muse, mutect2, varscan2
- HSPA12B | c.279C>A p.G93= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV54768481, COSV54769490; called by muse, mutect2, varscan2
- HSPA6 | c.786G>T p.L262= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV59063041; called by muse, mutect2, varscan2
- ITGA5 | c.2637C>T p.G879= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV53221110; called by muse, mutect2, varscan2
- JCAD | c.717G>A p.E239= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as COSV64762020; called by muse, mutect2, varscan2
- LAMA5 | c.10461C>T p.F3487= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV53374148; called by muse, mutect2, varscan2
- LBX1 | c.459C>T p.A153= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV64622197; called by muse, mutect2, varscan2
- LILRB1 | c.357C>T p.F119= (on ENST00000427581; = p.F83= on NM_006669.6) | Silent (SNP) | VAF 88/211 reads (42%) | catalogued as COSV61122215; called by muse, mutect2, varscan2
- LILRB2 | c.699T>C p.P233= | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as COSV58748588; called by muse, varscan2
- MAN1B1 | c.1923C>T p.I641= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV65371925; called by muse, mutect2
- MUC16 | c.15360T>C p.S5120= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as COSV67479816; called by muse, mutect2, varscan2
- MUC17 | c.8346C>A p.V2782= | Silent (SNP) | VAF 84/324 reads (26%) | catalogued as COSV60301920, COSV60306283; called by muse, mutect2, varscan2
- MUC4 | c.2610C>T p.G870= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs979886467, COSV62203534; called by muse, mutect2
- NAAA | c.564G>A p.K188= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV54431614; called by muse, mutect2, varscan2
- NAALAD2 | c.1782G>A p.L594= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV58961709; called by muse, mutect2, varscan2
- NLRP7 | c.411C>A p.T137= | Silent (SNP) | VAF 248/483 reads (51%) | catalogued as rs980251570, COSV60182858; called by muse, mutect2, varscan2
- NTM | c.273G>T p.L91= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV66196839; called by muse, mutect2, varscan2
- OR5D18 | c.558C>T p.L186= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV61738891; called by muse, mutect2, varscan2
- PCDH15 | c.4614T>A p.A1538= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as COSV64727988; called by muse, mutect2
- PDE10A | c.2154G>A p.K718= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV63099670; called by muse, mutect2, varscan2
- PLCXD3 | c.723G>A p.S241= | Silent (SNP) | VAF 20/146 reads (14%) | catalogued as rs375308462; called by muse, mutect2, varscan2
- PRKCI | c.1119G>A p.G373= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV55523210; called by muse, mutect2, varscan2
- PRMT7 | c.897C>T p.F299= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100266731; called by muse, mutect2, varscan2
- PTPRN2 | c.1530G>A p.A510= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs188565967; called by muse, mutect2, varscan2
- RASD2 | c.207C>G p.L69= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as COSV53353755; called by muse, mutect2, varscan2
- RGS10 | c.195A>G p.A65= (on ENST00000369101; = p.A59= on NM_002925.3) | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs746100354, COSV64862696; called by mutect2, varscan2
- SAP130 | c.2476C>T p.L826= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as COSV52103802; called by muse, mutect2, varscan2
- SEMA5B | c.1093T>C p.L365= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs370171745; called by muse, mutect2, varscan2
- SIPA1L1 | c.2682C>T p.S894= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs759321256, COSV62168272; called by muse, mutect2, varscan2
- SLC25A39 | c.696G>C p.L232= (on ENST00000377095 / NM_001143780.3; = p.L224= on NM_016016.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/54 reads (70%) | catalogued as COSV56589579; called by muse, mutect2, varscan2
- SLC4A11 | c.60T>C p.H20= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV66264319; called by muse, mutect2
- SORCS3 | c.2166G>A p.K722= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV63799210; called by muse, mutect2, varscan2
- SPATA17 | c.1044A>G p.S348= | Silent (SNP) | VAF 48/110 reads (44%) | catalogued as COSV65123601; called by muse, mutect2, varscan2
- SYNE2 | c.2079A>G p.E693= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV59972884; called by muse, mutect2, varscan2
- SYTL2 | c.2190A>G p.L730= (on ENST00000528231 / NM_001162951.2; = p.L706= on NM_032943.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs755491253, COSV60364586; called by muse, mutect2, varscan2
- TNN | c.1161C>T p.P387= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV53437415; called by muse, mutect2, varscan2
- TSHZ2 | c.2346T>C p.S782= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as rs1409015191, COSV61587918, COSV61592088; called by muse, mutect2, varscan2
- USP34 | c.7107G>A p.V2369= | Silent (SNP) | VAF 88/248 reads (35%) | catalogued as rs1445414322, COSV68407728; called by muse, varscan2
- ZAN | c.1170G>T p.G390= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV61817885; called by muse, mutect2, varscan2
- ZNF536 | c.471C>T p.P157= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV62835879, COSV62836698; called by muse, mutect2, varscan2
- AC024940.1 | n.4602A>T | RNA (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- AGAP2 | chr12:57742017 G>T | 5'Flank (SNP) | VAF 23/75 reads (31%) | catalogued as COSV57732728; called by muse, mutect2, varscan2
- FAM161A | c.1583+831G>C | Intron (SNP) | VAF 23/443 reads (5%) | catalogued as COSV100281139, COSV56769062; called by muse, mutect2
- MRPL3 | c.630-7953G>T | Intron (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99394646; called by muse, mutect2, varscan2
- PLXNA4 | c.1372-87002T>G | Intron (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100322688, COSV100326545; called by muse, mutect2
